Somatic mutation profile of tumor specimen TARGET-20-PARJVU-03A (aliquot TARGET-20-PARJVU-03A-01D) from TARGET case TARGET-20-PARJVU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,134 days).
Specimen TARGET-20-PARJVU-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c58a6a3-9b92-4195-9cb4-88711107ac17.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARJVU-14A (Bone Marrow Normal), aliquot TARGET-20-PARJVU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0899a11b-6b61-48e7-916d-8dc5eed2fe51

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 48/126 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TET2 | c.5635G>A p.E1879K | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54427352; called by muse, mutect2, varscan2
- ASXL2 | c.1465_1466delinsGTGCCC p.L489Vfs*11 | Frame Shift Ins (INS) | VAF 53/153 reads (35%) | called by pindel, varscan2*
- PHF6 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
